Somatic mutation profile of tumor specimen TARGET-10-PARFHH-09A (aliquot TARGET-10-PARFHH-09A-01D) from TARGET case TARGET-10-PARFHH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,073 days).
Specimen TARGET-10-PARFHH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 543e153f-9f9c-4b4f-8040-9bd30dee161b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFHH-14A (Bone Marrow Normal), aliquot TARGET-10-PARFHH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96607c86-d222-41cd-90e3-6da36738be66

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.2539G>A p.V847I | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.239); catalogued as rs371147537; called by muse, mutect2, varscan2
- CDH2 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs200263846, COSV52291562; called by muse, mutect2, varscan2
- CTNNA2 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- GAS2 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM110B | c.-18G>A | 5'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as rs371192216; called by muse, varscan2
